Somatic mutation profile of tumor specimen TCGA-D5-5537-01A (aliquot TCGA-D5-5537-01A-21D-1924-10) from TCGA case TCGA-D5-5537, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Age at diagnosis: 83.5 years (30,505 days).
Specimen TCGA-D5-5537-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e983936c-4458-48de-a72e-93dfcddb4e8c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D5-5537-10A (Blood Derived Normal), aliquot TCGA-D5-5537-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8049971-5783-45be-bffc-4ffb5cc3005c

The open-access MAF lists 109 somatic variants for this specimen: 77 protein-altering or splice-affecting, 31 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 31, Nonsense Mutation 8, Frame Shift Ins 3, Splice Site 2, Frame Shift Del 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 19/25 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 61/125 reads (49%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 30/43 reads (70%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- MTOR | c.5395G>A p.E1799K | Missense Mutation (SNP) | VAF 35/64 reads (55%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.463); catalogued as rs863225264, CM156279, COSV63869964; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- A2M | c.1356C>A p.F452L | Missense Mutation (SNP) | VAF 52/71 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV59382460; called by muse, mutect2, varscan2
- ADGRB3 | c.4471G>A p.E1491K | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.87); PolyPhen benign (0.108); catalogued as COSV53233435, COSV53251473; called by muse, mutect2, varscan2
- AHNAK2 | c.3254A>G p.E1085G | Missense Mutation (SNP) | VAF 43/56 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV60906803; called by muse, mutect2, varscan2
- AL592490.1 | c.1913G>T p.R638L | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.357); catalogued as rs781466949, COSV69424350, COSV69427254; called by muse, mutect2, varscan2
- AMER1 | c.1591C>T p.R531* | Nonsense Mutation (SNP) | VAF 90/105 reads (86%) | catalogued as CM117716, COSV57662882, COSV57669568; called by muse, mutect2, varscan2
- ANK2 | c.8569G>T p.E2857* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as COSV52144197, COSV52156267, COSV52176732; called by muse, mutect2, varscan2
- ANKRD30A | c.2575A>G p.K859E (on ENST00000611781; = p.K803E on NM_052997.2) | Missense Mutation (SNP) | VAF 38/229 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1169265636, COSV64603145; called by muse, mutect2, varscan2
- ARHGAP35 | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68329054; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3031G>T p.D1011Y | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV63243825; called by muse, mutect2, varscan2
- BRD3 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs370821220; called by muse, mutect2, varscan2
- CACNA1H | c.5375G>A p.S1792N | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.245); catalogued as COSV52352482; called by muse, mutect2, varscan2
- CCDC42 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as rs942378045, COSV53447943; called by muse, mutect2, varscan2
- CHD1L | c.1705+2T>G p.X569_splice | Splice Site (SNP) | VAF 31/55 reads (56%) | catalogued as rs587622399, COSV63612601; called by muse, mutect2, varscan2
- CLASRP | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.11); catalogued as COSV55514131; called by muse, mutect2, varscan2
- COL4A1 | c.4982G>A p.R1661H | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750538677, COSV65420695; called by muse, mutect2, varscan2
- CYRIA | c.482C>A p.T161K | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV62863654; called by muse, mutect2
- DNAH1 | c.7380C>A p.D2460E | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs1428527168, COSV101326596; called by muse, mutect2, varscan2
- DNAH17 | c.12103G>A p.A4035T | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.113); catalogued as rs746227487, COSV67749301; called by muse, mutect2, varscan2
- DPY19L2 | c.2164G>T p.D722Y | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61038476; called by muse, mutect2, varscan2
- DST | c.1790A>G p.N597S (on ENST00000361203 / NM_001374722.1; = p.N271S on NM_001723.6) | Missense Mutation (SNP) | VAF 43/62 reads (69%) | SIFT tolerated (0.77); PolyPhen benign (0.033); catalogued as COSV54996005; called by muse, mutect2, varscan2
- FBXO41 | c.743T>G p.L248R | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99721449; called by muse, mutect2, varscan2
- FUOM | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 19/35 reads (54%) | catalogued as COSV53369127; called by muse, mutect2, varscan2
- GATA5 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs1169825825, COSV53345119; called by muse, mutect2, varscan2
- GJA8 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs782253888, COSV53787656; called by muse, mutect2, varscan2
- GK2 | c.1620G>T p.M540I | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV62625925; called by muse, mutect2, varscan2
- GNB3 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373892759; called by muse, mutect2, varscan2
- GNB5 | c.1108G>A p.V370I (on ENST00000261837 / NM_016194.4; = p.V328I on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs763538889, COSV55897720; called by muse, mutect2, varscan2
- GRIA2 | c.1321C>T p.R441C | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs761885028, COSV52381359; called by muse, mutect2, varscan2
- GRIK4 | c.1378C>T p.R460* | Nonsense Mutation (SNP) | VAF 16/20 reads (80%) | catalogued as rs1377111124, COSV70799410; called by muse, mutect2, varscan2
- HYDIN | c.6569G>A p.R2190H | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs776491989, COSV59257902; called by muse, mutect2, varscan2
- IFT140 | c.2831C>T p.S944F | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV99560107; called by muse, mutect2, varscan2
- IGLV5-45 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.211); catalogued as rs368334334; called by muse, mutect2, varscan2
- INO80 | c.1701G>A p.W567* | Nonsense Mutation (SNP) | VAF 15/34 reads (44%) | catalogued as COSV62735881; called by muse, mutect2, varscan2
- KATNA1 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs756980278, COSV59501203; called by muse, mutect2, varscan2
- KDR | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99818287; called by muse, mutect2
- KIF26B | c.3032C>T p.A1011V | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs767436618, COSV63636206; called by muse, mutect2, varscan2
- KLHL4 | c.194G>T p.S65I | Missense Mutation (SNP) | VAF 79/95 reads (83%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.033); catalogued as COSV64138686; called by muse, mutect2, varscan2
- MATN4 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 29/52 reads (56%) | PolyPhen benign (0.053); catalogued as rs1308939445, COSV59212550, COSV59215522; called by muse, mutect2, varscan2
- MEGF10 | c.1960G>A p.A654T | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.318); catalogued as rs754091432, COSV57244268, COSV99175120; called by muse, mutect2, varscan2
- MYBPC2 | c.2707G>T p.A903S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV63093120; called by muse, mutect2, varscan2
- MYO1D | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 49/161 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772624904, COSV100554719; called by muse, mutect2, varscan2
- NALCN | c.2854G>A p.D952N | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.9); catalogued as COSV99216711; called by muse, mutect2, varscan2
- OR13H1 | c.235C>G p.P79A | Missense Mutation (SNP) | VAF 138/162 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as rs747560114, COSV58547006; called by muse, mutect2, varscan2
- OR1B1 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1165334474, COSV59171075; called by muse, mutect2, varscan2
- OR2W3 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.806); catalogued as rs759398397, COSV64455968; called by muse, mutect2, varscan2
- OR6Y1 | c.706G>T p.A236S | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.033); catalogued as rs767981273, COSV56928038; called by muse, mutect2, varscan2
- PDCD4 | c.533A>G p.H178R | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1351374271, COSV54521678; called by muse, mutect2, varscan2
- PTK2B | c.1189A>T p.I397L | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV57749372; called by muse, mutect2, varscan2
- PXDNL | c.2452G>T p.V818L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as COSV62476855; called by muse, mutect2, varscan2
- RASGRF1 | c.1862G>A p.S621N | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs747677216, COSV69176316, COSV69182622; called by muse, mutect2, varscan2
- SMO | c.734C>T p.T245M | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs765318599, COSV50824173, COSV50825282; called by muse, mutect2, varscan2
- SPATA17 | c.782C>T p.T261M | Missense Mutation (SNP) | VAF 106/175 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs148098301; called by muse, mutect2, varscan2
- STAT5A | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV61805632; called by muse, mutect2, varscan2
- STX18 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV60371421; called by muse, mutect2, varscan2
- SYNE2 | c.9535A>C p.N3179H | Missense Mutation (SNP) | VAF 125/168 reads (74%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs747161566, COSV59938682; called by muse, mutect2, varscan2
- TAF1L | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as rs567313961, COSV54256449, COSV54267807; called by muse, mutect2, varscan2
- TAS2R3 | c.325C>G p.L109V | Missense Mutation (SNP) | VAF 106/189 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56091533; called by muse, mutect2, varscan2
- TBC1D10C | c.706C>T p.H236Y | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as COSV56701820; called by muse, mutect2, varscan2
- TIA1 | c.730C>T p.R244* (on ENST00000433529 / NM_001351511.1; = p.R233* on NM_022037.4 and 9 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 61/138 reads (44%) | catalogued as COSV57005498; called by muse, mutect2, varscan2
- TRAPPC13 | c.334C>A p.L112I | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV51556032; called by muse, mutect2, varscan2
- UBE2Q1 | c.1235dup p.N412Kfs*31 | Frame Shift Ins (INS) | VAF 32/113 reads (28%) | catalogued as rs1415370636, COSV52726242; called by mutect2, varscan2
- XRCC1 | c.1190C>T p.P397L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV53447068; called by muse, mutect2, varscan2
- ZEB2 | c.3293A>C p.K1098T | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.351); catalogued as COSV57950643; called by muse, mutect2, varscan2
- ZMYM4 | c.4103G>T p.C1368F | Missense Mutation (SNP) | VAF 65/116 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV58906709; called by muse, mutect2, varscan2
- ZMYND10 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as rs199729765, COSV51599844; called by muse, mutect2, varscan2
- ZNF335 | c.2501C>T p.P834L | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as COSV59815827; called by muse, mutect2, varscan2
- ZNF827 | c.363C>A p.S121R | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65224542; called by muse, mutect2, varscan2
- APC | c.2739_2748del p.H913Qfs*39 | Frame Shift Del (DEL) | VAF 13/66 reads (20%) | called by mutect2, pindel, varscan2
- KIR2DS4 | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 20/118 reads (17%) | called by muse, mutect2, varscan2
- PIK3C2A | c.1327+1G>T p.X443_splice | Splice Site (SNP) | VAF 7/98 reads (7%) | called by muse, mutect2
- SOX9 | c.1317dup p.Y440Vfs*138 | Frame Shift Ins (INS) | VAF 26/93 reads (28%) | called by mutect2, pindel, varscan2
- WDSUB1 | c.761dup p.V255Sfs*7 | Frame Shift Ins (INS) | VAF 77/204 reads (38%) | called by mutect2, pindel, varscan2
- ZFP36L1 | c.529del p.H177Tfs*56 | Frame Shift Del (DEL) | VAF 28/45 reads (62%) | called by mutect2, pindel, varscan2
- ABCA12 | c.7596C>T p.V2532= (on ENST00000272895 / NM_173076.3; = p.V2214= on NM_015657.3) | Silent (SNP) | VAF 15/117 reads (13%) | catalogued as rs372152172, COSV55948331; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- AC004922.1 | c.1264C>T p.L422= | Silent (SNP) | VAF 49/90 reads (54%) | catalogued as COSV53162554; called by muse, mutect2, varscan2
- ADAM7 | c.465G>A p.V155= | Silent (SNP) | VAF 44/81 reads (54%) | catalogued as COSV51534578; called by muse, mutect2, varscan2
- ADCY9 | c.1419C>T p.I473= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs765382815, COSV53571179; called by muse, mutect2, varscan2
- ADGRL4 | c.1920C>T p.H640= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs367751734; called by muse, mutect2, varscan2
- AEBP1 | c.3036C>T p.T1012= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as rs1200792568, COSV56255119; called by muse, mutect2, varscan2
- BEND7 | c.868C>A p.R290= | Silent (SNP) | VAF 51/204 reads (25%) | catalogued as COSV61987087; called by muse, mutect2, varscan2
- BIRC6 | c.12390T>C p.Y4130= | Silent (SNP) | VAF 52/130 reads (40%) | catalogued as COSV101428533; called by mutect2, varscan2
- CELF3 | c.933C>T p.P311= | Silent (SNP) | VAF 40/55 reads (73%) | catalogued as rs1157048808, COSV51881350; called by muse, mutect2, varscan2
- CNTN1 | c.2595G>A p.S865= | Silent (SNP) | VAF 39/46 reads (85%) | catalogued as rs145714777, COSV61636941; called by muse, mutect2, varscan2
- CPA1 | c.828C>T p.H276= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as rs781912694, COSV50568080; called by muse, mutect2, varscan2
- CSPG4 | c.774C>A p.G258= | Silent (SNP) | VAF 52/98 reads (53%) | catalogued as COSV57889901; called by muse, mutect2, varscan2
- DCAF4L1 | c.339C>T p.H113= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as rs777108280, COSV60786333; called by muse, mutect2, varscan2
- ENPEP | c.435G>A p.P145= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV54446577; called by muse, mutect2, varscan2
- GLI3 | c.2865G>A p.T955= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs761642540, COSV67884755; called by muse, mutect2, varscan2
- KIAA1217 | c.3651G>A p.K1217= | Silent (SNP) | VAF 44/86 reads (51%) | catalogued as rs760391589, COSV56811933; called by muse, mutect2, varscan2
- LMTK2 | c.705G>A p.G235= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV99807354; called by muse, mutect2, varscan2
- LRRC6 | c.1020C>T p.Y340= | Silent (SNP) | VAF 37/65 reads (57%) | catalogued as rs745624673, COSV51537406; ClinVar: likely benign; called by muse, mutect2, varscan2
- MFHAS1 | c.2961C>T p.C987= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as COSV52279658; called by muse, mutect2, varscan2
- NT5C1B | c.870C>T p.Y290= (on ENST00000359846 / NM_001199086.2; = p.Y230= on NM_033253.4) | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs746909085, COSV58394165; called by muse, mutect2, varscan2
- OR10J5 | c.669C>G p.S223= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV100604631, COSV58384737; called by muse, mutect2, varscan2
- PAXBP1 | c.1050C>T p.S350= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as COSV51606330; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.831G>A p.P277= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs1283118619, COSV99461621; called by muse, mutect2, varscan2
- PPP2R3B | c.402C>T p.R134= | Silent (SNP) | VAF 59/386 reads (15%) | catalogued as COSV66812651; called by muse, mutect2, varscan2
- RSPH6A | c.1395G>A p.T465= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs748324816, COSV55569808; called by muse, mutect2, varscan2
- SLC36A3 | c.507C>T p.H169= | Silent (SNP) | VAF 55/88 reads (63%) | catalogued as rs764624103, COSV58855390; called by muse, mutect2, varscan2
- SMARCA4 | c.1959G>A p.P653= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as rs757029847, COSV60785781; ClinVar: likely benign; called by muse, mutect2, varscan2
- SNED1 | c.417C>T p.P139= | Silent (SNP) | VAF 46/130 reads (35%) | catalogued as rs769755879, COSV60018494; called by muse, mutect2, varscan2
- TLR3 | c.204C>T p.A68= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as rs201229975, COSV57167280; called by muse, mutect2, varscan2
- TTN | c.48039G>A p.P16013= (on ENST00000591111; = p.P8589= on NM_003319.4) | Silent (SNP) | VAF 46/103 reads (45%) | catalogued as rs773148195, COSV59869509; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- ZSWIM3 | c.2010C>T p.D670= | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as rs537547455, COSV54844970; called by muse, mutect2, varscan2
- MYL3 | chr3:46830424 C>T | 3'Flank (SNP) | VAF 13/43 reads (30%) | catalogued as COSV70133482; called by muse, mutect2, varscan2
